Somatic mutation profile of tumor specimen 0DITT1 from CCDI case PBBTWN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Choroid plexus papilloma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.2 years (6,285 days).
Specimen 0DITT1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 621e34af-c917-4031-9572-95dbcd7fda06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DITSA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fd2a246-f9c5-4610-afcc-2085c05680e8

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DRP2 | c.2002G>T p.D668Y | Missense Mutation (SNP) | VAF 66/1310 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65811083; called by muse, mutect2
- MPP2 | c.1070G>A p.R357H (on ENST00000461854 / NM_001278372.2; = p.R333H on NM_005374.5) | Missense Mutation (SNP) | VAF 86/1199 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs369632162; called by muse, mutect2
- ZNF827 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 34/1396 reads (2%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1311756464, COSV101061508; called by muse, mutect2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 41/1470 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- OR14A16 | c.416G>A p.C139Y | Missense Mutation (SNP) | VAF 59/1311 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- SORL1 | c.3190T>C p.Y1064H | Missense Mutation (SNP) | VAF 236/987 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- POLL | c.762C>A p.L254= | Silent (SNP) | VAF 164/555 reads (30%) | called by muse, mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
